Somatic mutation profile of tumor specimen TCGA-24-1104-01A (aliquot TCGA-24-1104-01A-01W-0488-09) from TCGA case TCGA-24-1104, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.2 years (20,527 days).
Specimen TCGA-24-1104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3b2fd65-542c-47db-9761-757d3e01fe8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1104-10A (Blood Derived Normal), aliquot TCGA-24-1104-10A-01W-0488-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7dc7b4f9-3bca-4c37-af9c-2af2b8aece59

The open-access MAF lists 92 somatic variants for this specimen: 71 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 20, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 59/139 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4622C>A p.S1541Y | Missense Mutation (SNP) | VAF 95/344 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV52638197, COSV52645997; called by muse, mutect2, varscan2
- ABCC2 | c.611T>A p.I204N | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100965666; called by muse, mutect2
- ADGRG4 | c.2843G>A p.G948E | Missense Mutation (SNP) | VAF 306/777 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV54955217; called by muse, mutect2, varscan2
- AIFM1 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 44/448 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99781504; called by muse, mutect2, varscan2
- ALCAM | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV60247887, COSV60256394; called by muse, mutect2, varscan2
- ARRB1 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV100758209; called by muse, mutect2
- ASMT | c.272G>T p.S91I | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV101172564; called by muse, mutect2
- BOLL | c.53T>C p.L18S | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV56574229; called by muse, mutect2, varscan2
- C14orf93 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.534); catalogued as COSV54440929; called by muse, mutect2, varscan2
- CA4 | c.644G>T p.R215M | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.704); catalogued as COSV99958537; called by muse, mutect2, varscan2
- CA4 | c.645G>C p.R215S | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.051); catalogued as COSV99958540; called by muse, mutect2, varscan2
- CCDC80 | c.942C>G p.D314E | Missense Mutation (SNP) | VAF 16/379 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52819994; called by muse, mutect2
- CECR2 | c.1286A>G p.K429R (on ENST00000342247 / NM_001290047.2; = p.K246R on NM_001290046.1) | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs778084870, COSV52837270, COSV52840437; called by muse, mutect2, varscan2
- CR1 | c.5044A>T p.S1682C | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV65455586, COSV65457132; called by muse, mutect2, varscan2
- DYNC1H1 | c.6154G>A p.V2052I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100795526; called by mutect2, varscan2
- ERCC6 | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 62/167 reads (37%) | catalogued as COSV63389787; called by muse, mutect2, varscan2
- FAM47C | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs781942309, COSV100792267, COSV63726287; called by muse, mutect2, varscan2
- FAT3 | c.6307A>T p.I2103F | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV53105735; called by muse, mutect2, varscan2
- FCAMR | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 109/382 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.174); catalogued as COSV61367600; called by muse, mutect2, varscan2
- GOLPH3L | c.360T>A p.D120E | Missense Mutation (SNP) | VAF 95/383 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55046026; called by muse, mutect2, varscan2
- GPALPP1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1370501447, COSV62705458; called by muse, mutect2, varscan2
- HIVEP2 | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 79/124 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV50010806; called by muse, mutect2, varscan2
- HOXA1 | c.47G>C p.S16T | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV56066092; called by muse, mutect2, varscan2
- HOXB1 | c.232A>T p.S78C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53317096; called by muse, mutect2, varscan2
- HTR2A | c.556T>C p.F186L | Missense Mutation (SNP) | VAF 97/216 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV66327196, COSV66327496; called by muse, mutect2, varscan2
- ITPR2 | c.3565C>A p.L1189I | Missense Mutation (SNP) | VAF 118/476 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV67268860; called by muse, mutect2, varscan2
- KANSL1L | c.1229A>T p.K410M | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99911090; called by muse, mutect2
- KBTBD6 | c.1481T>G p.M494R | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV65271203; called by muse, mutect2, varscan2
- MAD1L1 | c.981C>G p.S327R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99767879; called by muse, mutect2, varscan2
- MAP3K7CL | c.522G>C p.K174N | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.856); catalogued as COSV54509176, COSV54511667; called by muse, mutect2, varscan2
- MED4 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV51639182; called by muse, mutect2, varscan2
- MMRN1 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 146/292 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53337041; called by muse, mutect2, varscan2
- MYEF2 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 11/394 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV99982267; called by muse, mutect2
- NID2 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99357404; called by muse, mutect2
- NLGN3 | c.2341dup p.H781Pfs*2 (on ENST00000358741 / NM_181303.2; = p.H761Pfs*2 on NM_018977.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | catalogued as rs760052938; called by mutect2, varscan2
- NPAS3 | c.1983C>A p.D661E (on ENST00000356141 / NM_001164749.2; = p.D629E on NM_022123.3) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.133); catalogued as COSV100640761; called by muse, mutect2
- PIWIL2 | c.2180G>A p.G727D | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100769586; called by muse, mutect2
- POLE | c.6734C>A p.T2245N | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as COSV57679613; called by muse, mutect2, varscan2
- PTPRT | c.3874A>G p.T1292A | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV61978988; called by muse, mutect2
- PUM3 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67395590, COSV67396275; called by muse, mutect2, varscan2
- RASAL2 | c.1188G>C p.E396D | Missense Mutation (SNP) | VAF 124/595 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV62713484; called by muse, mutect2, varscan2
- RGS8 | c.301C>G p.L101V (on ENST00000367556 / NM_001369564.2; = p.L119V on NM_033345.3) | Missense Mutation (SNP) | VAF 145/489 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV51116058; called by muse, mutect2, varscan2
- RRM2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.127); catalogued as COSV58816601, COSV58817420; called by muse, mutect2
- RYK | c.1040T>C p.I347T (on ENST00000620660 / NM_001005861.2; = p.I344T on NM_002958.4) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV56061966; called by muse, mutect2, varscan2
- SC5D | c.66G>T p.W22C | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99873258; called by muse, mutect2
- SDC1 | c.464G>T p.R155M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV54339704; called by muse, mutect2, varscan2
- SERPINA9 | c.73A>C p.N25H | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.195); catalogued as COSV100098928; called by muse, mutect2
- SHF | c.809C>A p.P270Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV52050371; called by muse, mutect2, varscan2
- SI | c.3784T>C p.Y1262H | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV100015540, COSV100017464; called by muse, mutect2
- SLC13A1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52010302; called by muse, mutect2, varscan2
- SLC25A4 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55668800; called by muse, mutect2, varscan2
- SLC5A3 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758127; called by muse, mutect2, varscan2
- SYCE1 | c.671C>A p.T224N (on ENST00000343131 / NM_001143764.3; = p.T188N on NM_130784.3) | Missense Mutation (SNP) | VAF 66/77 reads (86%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.509); catalogued as COSV58217049; called by muse, mutect2, varscan2
- TCOF1 | c.3361G>A p.G1121R (on ENST00000377797 / NM_001135243.1; = p.G1044R on NM_000356.4) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV100078025, COSV60348117; called by muse, mutect2, varscan2
- TMEM71 | c.287G>C p.S96T | Missense Mutation (SNP) | VAF 162/882 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV100785681, COSV63457258; called by muse, mutect2, varscan2
- TRPM8 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100224671; called by muse, mutect2, varscan2
- TRPM8 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100224675; called by muse, mutect2, varscan2
- UBAP2 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 286/939 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62546374, COSV62546530; called by muse, mutect2, varscan2
- UPB1 | c.927C>G p.D309E | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV58113403; called by muse, mutect2, varscan2
- USP48 | c.2820A>T p.K940N | Missense Mutation (SNP) | VAF 141/278 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV57609559; called by muse, mutect2, varscan2
- USPL1 | c.3240C>G p.D1080E | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99687638; called by muse, mutect2
- VILL | c.1438dup p.H480Pfs*38 | Frame Shift Ins (INS) | VAF 18/129 reads (14%) | catalogued as rs753585188; called by mutect2, varscan2
- ZNF16 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 187/1118 reads (17%) | catalogued as COSV52763528; called by muse, mutect2, varscan2
- ZNF438 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100062905; called by muse, mutect2, varscan2
- ZNF799 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 267/838 reads (32%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.555); catalogued as COSV70122540, COSV70122883; called by muse, mutect2
- ZXDA | c.1775G>T p.S592I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100699488; called by muse, mutect2, varscan2
- BZW2 | c.680_691del p.V227_F230del | In Frame Del (DEL) | VAF 35/87 reads (40%) | called by mutect2, pindel, varscan2
- CHD2 | c.4112_4137+3del p.X1371_splice | Splice Site (DEL) | VAF 36/329 reads (11%) | called by mutect2, pindel
- FCGBP | c.10619C>G p.A3540G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.466); called by muse, mutect2
- POU2F3 | c.955del p.S319Pfs*7 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | called by mutect2, pindel, varscan2
- ALAS1 | c.933G>C p.S311= | Silent (SNP) | VAF 25/175 reads (14%) | catalogued as COSV59627767, COSV59629368; called by muse, mutect2, varscan2
- CCDC15 | c.1587C>G p.G529= | Silent (SNP) | VAF 331/650 reads (51%) | catalogued as COSV61081533; called by muse, mutect2, varscan2
- CNTNAP1 | c.3195T>A p.P1065= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV52852163, COSV99227145; called by muse, mutect2, varscan2
- CNTRL | c.6124T>C p.L2042= | Silent (SNP) | VAF 75/215 reads (35%) | catalogued as rs1307429722, COSV53046571; called by muse, mutect2, varscan2
- CSMD3 | c.5115C>A p.G1705= (on ENST00000297405 / NM_001363185.1; = p.G1601= on NM_052900.3) | Silent (SNP) | VAF 101/246 reads (41%) | catalogued as COSV52167279, COSV99835799; called by muse, mutect2, varscan2
- HEATR5B | c.5853G>A p.A1951= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as rs750248993, COSV51852308; called by muse, mutect2, varscan2
- KIAA1217 | c.900C>T p.P300= | Silent (SNP) | VAF 36/334 reads (11%) | catalogued as rs200740349, COSV100287527, COSV56816225, COSV56819361; called by muse, varscan2
- PDCD6IP | c.1758A>T p.T586= | Silent (SNP) | VAF 41/156 reads (26%) | catalogued as COSV56242936; called by muse, mutect2, varscan2
- RABGAP1 | c.336A>C p.V112= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV58060126; called by muse, mutect2, varscan2
- RGL1 | c.171A>G p.T57= (on ENST00000360851 / NM_001297672.2; = p.T92= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 130/891 reads (15%) | catalogued as rs1357563547, COSV58984550; called by muse, mutect2, varscan2
- RGR | c.315C>T p.A105= | Silent (SNP) | VAF 14/207 reads (7%) | catalogued as rs1183439848, COSV100813003; called by muse, mutect2
- RGS18 | c.198T>G p.S66= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV66508042; called by muse, mutect2, varscan2
- SEMA6A | c.48T>G p.A16= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV57310920; called by muse, mutect2, varscan2
- SKIDA1 | c.2586G>T p.G862= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as COSV71610890; called by muse, mutect2, varscan2
- SLC28A3 | c.1464C>T p.Y488= | Silent (SNP) | VAF 72/270 reads (27%) | catalogued as rs774772001, COSV66152974; called by muse, mutect2, varscan2
- SLCO4A1 | c.975C>T p.A325= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs572345402, COSV53890607; called by muse, mutect2, varscan2
- SNIP1 | c.1092C>T p.S364= | Silent (SNP) | VAF 71/390 reads (18%) | catalogued as COSV99953325; called by muse, mutect2, varscan2
- SOX6 | c.279A>C p.R93= | Silent (SNP) | VAF 52/240 reads (22%) | catalogued as COSV57044833; called by muse, mutect2, varscan2
- TESK2 | c.1455C>G p.R485= | Silent (SNP) | VAF 32/289 reads (11%) | catalogued as COSV59151775, COSV59155985; called by muse, mutect2, varscan2
- TIMP4 | c.316C>T p.L106= | Silent (SNP) | VAF 14/276 reads (5%) | catalogued as COSV99826132; called by muse, mutect2
- COX6B1 | c.-21C>T | 5'UTR (SNP) | VAF 27/58 reads (47%) | catalogued as COSV55837709; called by muse, mutect2, varscan2
